Somatic mutation profile of tumor specimen ALCH-B1XC-TTP1-A (aliquot ALCH-B1XC-TTP1-A-3-0-D-A76I-36) from ALCHEMIST case ALCH-B1XC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.8 years (22,563 days).
Specimen ALCH-B1XC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7005e6e-6888-4568-a5c7-c63c30d5a5e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XC-NB1-A (Blood Derived Normal), aliquot ALCH-B1XC-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acc1040e-cc9e-4956-8fb8-89ff4fc99fef

The open-access MAF lists 212 somatic variants for this specimen: 143 protein-altering or splice-affecting, 45 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 45, Nonsense Mutation 15, Intron 11, 5'UTR 6, Frame Shift Del 4, Splice Site 3, 3'UTR 3, RNA 3, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 46/366 reads (13%) | catalogued as rs886043410, CM002755, COSV61531528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.50_51del p.Q17Rfs*26 | Frame Shift Del (DEL) | VAF 74/509 reads (15%) | catalogued as rs587781912, COSV64297849; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS16 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777610990, COSV56978893; called by muse, mutect2, varscan2
- ADAMTS20 | c.3099C>G p.C1033W | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166101; called by muse, mutect2, varscan2
- AMOTL2 | c.2168G>A p.S723N (on ENST00000422605; = p.S724N on NM_016201.4) | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs749486237; called by muse, mutect2, varscan2
- ANKK1 | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392725; called by muse, mutect2, varscan2
- AOC2 | c.2249C>A p.P750H (on ENST00000253799 / NM_009590.4; = p.P723H on NM_001158.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV53828254; called by muse, mutect2
- CARD14 | c.1226del p.E409Gfs*51 | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | catalogued as COSV60125027; called by mutect2, pindel, varscan2
- CDH10 | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52571652; called by muse, mutect2, varscan2
- COL11A2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 54/411 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.419); catalogued as rs866332399; called by muse, mutect2, varscan2
- COL7A1 | c.5327G>T p.G1776V | Missense Mutation (SNP) | VAF 49/355 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM112241; called by muse, mutect2, varscan2
- CRACD | c.2513G>C p.G838A | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV99948771; called by muse, varscan2
- CYP1B1 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV53192002; called by muse, mutect2, varscan2
- EMILIN3 | c.835C>G p.H279D | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100182686; called by muse, mutect2, varscan2
- EXTL2 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.06); catalogued as rs1410376718; called by muse, mutect2, varscan2
- FIZ1 | c.758A>G p.Q253R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs1211803924; called by muse, mutect2
- GFI1B | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 37/377 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148996720; called by muse, mutect2, varscan2
- GIMAP2 | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs756855631; called by muse, mutect2, varscan2
- GRM8 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 72/490 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58813894; called by muse, mutect2, varscan2
- HECW1 | c.1985C>A p.P662H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV101222614, COSV101222856; called by muse, mutect2, varscan2
- HK2 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 65/609 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs763967521, COSV51874863, COSV99309445; called by muse, mutect2, varscan2
- HS3ST3A1 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV52375712; called by muse, mutect2, varscan2
- HUWE1 | c.2359G>C p.D787H | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53344278; called by muse, mutect2, varscan2
- IL2 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.317); catalogued as COSV56986190; called by muse, mutect2
- KRT8 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 55/469 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV53179438; called by muse, mutect2, varscan2
- LZTS2 | c.896G>C p.R299P | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs531530897; called by mutect2, varscan2
- MFAP3L | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs754706345; called by muse, mutect2, varscan2
- MTMR9 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1205562164; called by muse, mutect2, varscan2
- MTOR | c.4555G>A p.A1519T | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63868966; called by muse, mutect2
- MUC12 | c.1892G>T p.G631V (on ENST00000379442; = p.G488V on NM_001164462.1) | Missense Mutation (SNP) | VAF 37/670 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1446457415; called by muse, mutect2
- NACAD | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as rs1562928702, COSV71989620; called by muse, mutect2, varscan2
- NALCN | c.3112C>A p.L1038I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.487); catalogued as rs771741587; called by muse, mutect2, varscan2
- NDN | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV99045561; called by muse, mutect2, varscan2
- NOTCH2 | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.022); catalogued as COSV56687797, COSV56693459; called by muse, mutect2, varscan2
- OR7A5 | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs753219648; called by muse, mutect2
- PCSK9 | c.1118G>T p.S373I | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768686622; called by muse, mutect2, varscan2
- PHF3 | c.2846A>G p.K949R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1364157212; called by muse, mutect2
- PKD1 | c.8506T>G p.F2836V | Missense Mutation (SNP) | VAF 37/534 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs780161620; called by muse, mutect2
- PLCH1 | c.1684C>T p.R562W (on ENST00000340059 / NM_001130960.2; = p.R574W on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs773887107, COSV100396346; called by muse, mutect2
- RALGPS1 | c.670A>T p.M224L | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1211656976; called by muse, mutect2, varscan2
- SGIP1 | c.1448G>T p.R483I | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99392197; called by muse, mutect2, varscan2
- SPTLC3 | c.88A>T p.T30S | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV65469048; called by muse, mutect2, varscan2
- SYNE1 | c.15124G>T p.E5042* (on ENST00000367255 / NM_182961.4; = p.E4971* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 40/342 reads (12%) | catalogued as COSV99584697; called by muse, mutect2, varscan2
- TGFBR1 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 36/380 reads (9%) | catalogued as rs200595614, COSV66625422; called by muse, mutect2
- TP53 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665474, COSV52751752, COSV52987532; called by muse, mutect2, varscan2
- TRPM6 | c.4675C>G p.L1559V | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.015); catalogued as COSV62522079; called by muse, mutect2
- USP34 | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1202841149, COSV68398328; called by muse, mutect2, varscan2
- ZDHHC14 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as rs971952713, COSV58193491; called by muse, mutect2, varscan2
- ZFHX4 | c.6492G>C p.E2164D | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV51497761; called by muse, mutect2, varscan2
- ZNF251 | c.1270G>T p.V424L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV52956710; called by muse, mutect2, varscan2
- AC023055.1 | c.1427C>A p.S476* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | called by muse, mutect2, varscan2
- ACTL6A | c.25+1G>A p.X9_splice | Splice Site (SNP) | VAF 24/215 reads (11%) | called by muse, mutect2, varscan2
- AOC1 | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- ARMC12 | c.406G>T p.A136S (on ENST00000373866 / NM_001286574.2; = p.A163S on NM_145028.5) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.841); called by muse, mutect2
- BDP1 | c.5224G>T p.V1742F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- BMPR1A | c.374G>C p.C125S | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CCDC38 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2
- CCND2 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCT8L2 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CNTNAP5 | c.2971G>T p.G991W | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL26A1 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 32/259 reads (12%) | called by muse, mutect2, varscan2
- COL27A1 | c.528G>C p.Q176H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2
- COL6A6 | c.1578G>T p.L526F | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CYLD | c.2583A>T p.L861F | Missense Mutation (SNP) | VAF 72/505 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP11B1 | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 54/452 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DGKI | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.235); called by muse, mutect2
- DIAPH2 | c.1721G>C p.G574A | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1AKNMT | c.397G>T p.E133* (on ENST00000361735 / NM_015935.5; = p.E47* on NM_014955.3) | Nonsense Mutation (SNP) | VAF 42/389 reads (11%) | called by muse, mutect2, varscan2
- EIF3M | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ERI1 | c.328T>A p.Y110N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERICH3 | c.3861G>T p.E1287D | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FAM186A | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.199); called by muse, mutect2
- FMN2 | c.2753C>A p.A918E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXG1 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 67/484 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMD1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRMD1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GDPD2 | c.1257G>T p.R419S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- GK2 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.082); called by muse, mutect2
- GON4L | c.5278C>T p.L1760F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GRB14 | c.1025A>T p.Y342F | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.154); called by muse, varscan2
- GRIN2B | c.4157C>A p.P1386H | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HERC2 | c.12850G>C p.G4284R | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HPS3 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV3D-15 | c.168C>A p.Y56* | Nonsense Mutation (SNP) | VAF 64/309 reads (21%) | called by muse, mutect2, varscan2
- ITM2B | c.765A>C p.E255D | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- ITPRIPL2 | c.1579A>G p.T527A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by mutect2, varscan2
- KBTBD11 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- KIF21B | c.1824A>T p.E608D | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KLHL34 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT27 | c.517T>A p.F173I | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LIMD1 | c.334G>T p.G112W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- LRP1 | c.3520G>T p.D1174Y | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.3767-1G>T p.X1256_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- MAGED2 | c.1492del p.E498Rfs*78 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | called by mutect2, pindel, varscan2
- MAN2A2 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MGAT5B | c.1775C>G p.P592R (on ENST00000569840 / NM_001199172.2; = p.P590R on NM_144677.3) | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); called by muse, mutect2
- MINDY4 | c.2194G>T p.V732F | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2
- MPND | c.792C>G p.I264M | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.089); called by muse, mutect2
- MROH5 | c.1960C>A p.L654M | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MRS2 | c.302-2A>G p.X101_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MSL3 | c.1531C>T p.H511Y (on ENST00000312196 / NM_078629.4; = p.H345Y on NM_006800.4) | Missense Mutation (SNP) | VAF 35/333 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MVB12B | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYADM | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NAP1L3 | c.1252del p.Q418Rfs*33 | Frame Shift Del (DEL) | VAF 19/192 reads (10%) | called by pindel, varscan2
- NAV3 | c.6041C>A p.T2014N (on ENST00000397909 / NM_001024383.2; = p.T1992N on NM_014903.6) | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.4); called by muse, mutect2
- OPCML | c.470G>C p.C157S | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2
- OTC | c.900T>A p.F300L | Missense Mutation (SNP) | VAF 56/385 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOG | c.7667G>T p.R2556L | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- PAM | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PKHD1L1 | c.7675C>A p.P2559T | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRRC2C | c.2324G>A p.R775K (on ENST00000367742; = p.R773K on NM_015172.4) | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PTPN13 | c.4795G>A p.A1599T (on ENST00000411767 / NM_080683.3; = p.A1580T on NM_006264.3) | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RASAL1 | c.1667C>A p.P556Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RYR2 | c.5125A>T p.I1709F | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SCPEP1 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 33/244 reads (14%) | called by muse, mutect2, varscan2
- SEL1L3 | c.2083_2084insG p.L695Cfs*21 | Frame Shift Ins (INS) | VAF 15/125 reads (12%) | called by mutect2, pindel, varscan2
- SH3TC1 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- SLC2A5 | c.733A>T p.R245W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC30A10 | c.1049A>T p.H350L | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC38A8 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SLC9A6 | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.251); called by muse, varscan2
- SYTL2 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.118); called by muse, mutect2
- TAC3 | c.164C>A p.S55* | Nonsense Mutation (SNP) | VAF 47/427 reads (11%) | called by muse, mutect2, varscan2
- TACR1 | c.193A>T p.T65S | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, varscan2
- TAF2 | c.608A>T p.K203I | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TARBP1 | c.3449A>C p.E1150A | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX18 | c.961A>T p.R321W | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TENM1 | c.5204A>G p.E1735G | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- TIAM2 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- TNRC18 | c.6841C>A p.P2281T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAV5 | c.60T>A p.S20R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TRHDE | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TSNARE1 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- TTN | c.55742T>C p.V18581A (on ENST00000591111; = p.V11157A on NM_003319.4) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | PolyPhen probably damaging (0.99); called by muse, mutect2
- UBR4 | c.4658A>T p.H1553L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- WDR7 | c.4174G>T p.G1392* | Nonsense Mutation (SNP) | VAF 24/170 reads (14%) | called by muse, varscan2
- XKR5 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 55/497 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZFHX4 | c.5647A>T p.K1883* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- ZNF208 | c.2857G>T p.A953S | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF383 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF75D | c.1098G>T p.K366N | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ZNF804B | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- ZNF875 | c.1892G>A p.G631E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); called by muse, mutect2
- AASS | c.960A>T p.L320= | Silent (SNP) | VAF 63/493 reads (13%) | called by muse, mutect2, varscan2
- ACACB | c.4383C>A p.I1461= | Silent (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- ACSM2B | c.885T>A p.V295= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- AFDN | c.3222G>A p.A1074= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs771980173; called by muse, varscan2
- ALAD | c.105C>T p.I35= | Silent (SNP) | VAF 32/298 reads (11%) | called by muse, mutect2
- APOL4 | c.666G>C p.L222= (on ENST00000352371 / NM_145660.2; = p.L219= on NM_030643.4) | Silent (SNP) | VAF 46/321 reads (14%) | called by muse, mutect2, varscan2
- C6orf118 | c.1318T>C p.L440= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1411796397; called by muse, mutect2
- CBY2 | c.291C>T p.S97= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as rs952792286, COSV60117685; called by muse, mutect2, varscan2
- CELA2B | c.402C>G p.T134= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as rs938903556; called by muse, mutect2, varscan2
- CPB2 | c.729T>C p.S243= | Silent (SNP) | VAF 20/167 reads (12%) | catalogued as rs1190640250; called by muse, varscan2
- CRYBG1 | c.1368G>T p.A456= | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as rs1212712580, COSV64813059; called by muse, mutect2, varscan2
- DAPK1 | c.3315C>T p.A1105= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as rs1376872834; called by muse, mutect2, varscan2
- DNAH5 | c.3760C>A p.R1254= | Silent (SNP) | VAF 24/313 reads (8%) | catalogued as rs749162833, COSV54237035; called by muse, mutect2
- DOCK3 | c.1041C>T p.C347= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs1007360078; called by muse, mutect2, varscan2
- FCGBP | c.5814A>G p.E1938= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- FSCB | c.2109A>C p.P703= | Silent (SNP) | VAF 28/183 reads (15%) | catalogued as COSV61219453; called by muse, varscan2
- GSK3B | c.12G>A p.R4= | Silent (SNP) | VAF 32/264 reads (12%) | called by muse, mutect2, varscan2
- H2AZ1 | c.78G>A p.L26= | Silent (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2, varscan2
- HOOK2 | c.1866G>T p.A622= | Silent (SNP) | VAF 17/229 reads (7%) | catalogued as rs775514142, COSV53401512; called by muse, mutect2
- HPSE2 | c.396G>A p.A132= | Silent (SNP) | VAF 49/307 reads (16%) | catalogued as rs1243217388, COSV65197076; called by muse, mutect2, varscan2
- HTR2C | c.384C>G p.P128= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as COSV52204342; called by muse, mutect2, varscan2
- MUC17 | c.9762C>A p.T3254= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as COSV60302364; called by muse, mutect2, varscan2
- MYOG | c.445C>A p.R149= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV54096030; called by muse, mutect2, varscan2
- NCOR1 | c.6432G>C p.S2144= | Silent (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- NLGN4X | c.1383G>A p.A461= | Silent (SNP) | VAF 56/442 reads (13%) | catalogued as rs763976516, COSV52015401, COSV52015454; called by muse, mutect2, varscan2
- OR2L5 | c.327A>G p.A109= | Silent (SNP) | VAF 32/236 reads (14%) | catalogued as rs1404383294; called by muse, mutect2, varscan2
- OR56A5 | c.771C>A p.V257= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV60827111; called by muse, mutect2
- OSBPL8 | c.2629C>T p.L877= | Silent (SNP) | VAF 26/199 reads (13%) | called by muse, varscan2
- PCDHA4 | c.996C>A p.G332= | Silent (SNP) | VAF 30/260 reads (12%) | catalogued as rs782261316; called by muse, mutect2, varscan2
- PCLO | c.13875A>T p.A4625= | Silent (SNP) | VAF 35/276 reads (13%) | called by muse, mutect2, varscan2
- PIEZO2 | c.6495G>C p.L2165= | Silent (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2253G>A p.A751= | Silent (SNP) | VAF 49/345 reads (14%) | catalogued as rs199567899, COSV67049886; called by muse, mutect2, varscan2
- RNF165 | c.126C>A p.P42= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- SCN3A | c.1858C>A p.R620= | Silent (SNP) | VAF 33/309 reads (11%) | catalogued as rs1288869563, COSV51800546, COSV51814482; called by muse, mutect2, varscan2
- SHKBP1 | c.1662G>T p.R554= | Silent (SNP) | VAF 14/239 reads (6%) | catalogued as rs1237807448; called by muse, mutect2
- SLC6A1 | c.1161C>T p.S387= | Silent (SNP) | VAF 23/213 reads (11%) | called by muse, mutect2, varscan2
- SOX6 | c.540A>G p.T180= | Silent (SNP) | VAF 45/334 reads (13%) | called by muse, mutect2, varscan2
- SPTBN2 | c.93G>A p.S31= | Silent (SNP) | VAF 31/432 reads (7%) | catalogued as rs750767180; called by muse, mutect2
- SUN3 | c.819G>A p.P273= | Silent (SNP) | VAF 25/211 reads (12%) | catalogued as rs138815958; called by muse, mutect2, varscan2
- TAS2R38 | c.211C>T p.L71= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV71886083; called by muse, mutect2, varscan2
- TMEM150A | c.519T>A p.A173= (on ENST00000334462 / NM_001031738.3; = p.A120= on NM_153342.3) | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- TMPRSS15 | c.1539G>T p.V513= | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- TNFAIP3 | c.2028G>A p.K676= | Silent (SNP) | VAF 61/461 reads (13%) | catalogued as rs1476970838; called by muse, mutect2, varscan2
- ZAN | c.4480C>A p.R1494= | Silent (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- ZNF746 | c.1800A>T p.P600= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2
- BIN3 | c.-38T>C | 5'UTR (SNP) | VAF 33/206 reads (16%) | called by muse, mutect2, varscan2
- C3orf35 | chr3:37417265 A>G | 3'Flank (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- C4orf17 | c.*52C>A | 3'UTR (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2178G>A | 3'UTR (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- CRK | c.-59C>T | 5'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs989136034; called by muse, mutect2, varscan2
- DUS4L | c.357-76A>G | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- GPATCH8 | c.120+84C>A | Intron (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- HPRT1 | c.-56T>A | 5'UTR (SNP) | VAF 32/232 reads (14%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.-11C>A | 5'UTR (SNP) | VAF 54/498 reads (11%) | called by muse, mutect2, varscan2
- LHFPL5 | c.-21C>A | 5'UTR (SNP) | VAF 26/181 reads (14%) | called by muse, mutect2, varscan2
- MAPKAP1 | c.672-5861G>C | Intron (SNP) | VAF 7/70 reads (10%) | catalogued as COSV56372798; called by muse, mutect2, varscan2
- MDGA2 | c.281-41413C>A | Intron (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- MDGA2 | c.281-41414T>A | Intron (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- MRPS9 | c.652-1039A>G | Intron (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2, varscan2
- NFYC | c.387+1152A>T | Intron (SNP) | VAF 41/302 reads (14%) | called by muse, mutect2, varscan2
- OR4C4P | n.719G>T | RNA (SNP) | VAF 25/155 reads (16%) | catalogued as rs1446299135; called by muse, mutect2, varscan2
- PCCB | c.1198+32G>C | Intron (SNP) | VAF 38/358 reads (11%) | called by muse, mutect2
- POU2F2 | c.*140G>C | 3'UTR (SNP) | VAF 27/221 reads (12%) | called by muse, mutect2, varscan2
- RAI14 | c.36+29136T>A | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- ROPN1 | c.116+43G>C | Intron (SNP) | VAF 19/112 reads (17%) | catalogued as rs765224997; called by muse, mutect2
- SPATA31C1 | n.1366G>T | RNA (SNP) | VAF 54/644 reads (8%) | called by muse, mutect2
- SPATA31C1 | n.1475A>T | RNA (SNP) | VAF 52/601 reads (9%) | called by muse, mutect2
- TCEAL4 | c.-4C>A | 5'UTR (SNP) | VAF 37/292 reads (13%) | called by muse, mutect2, varscan2
- ZNF717 | c.184+62C>A | Intron (SNP) | VAF 18/110 reads (16%) | catalogued as rs1431907689; called by muse, mutect2, varscan2
